Somatic mutation profile of tumor specimen MP2PRT-PANUIX-TMP1-A (aliquot MP2PRT-PANUIX-TMP1-A-1-0-D-A83L-36) from MP2PRT case MP2PRT-PANUIX, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Acute lymphoblastic leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 2.8 years (1,015 days).
Specimen MP2PRT-PANUIX-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 12ba4536-89a0-468d-a36c-87c799193f2d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PANUIX-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PANUIX-NB1-A-1-0-D-A83L-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6630b483-3918-402c-939b-8ea325fe6f86

The open-access MAF lists 21 somatic variants for this specimen: 16 protein-altering or splice-affecting, 4 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 12, Silent 4, Splice Region 2, Intron 1, Frame Shift Ins 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- JAK2 | c.2047A>G p.R683G | Missense Mutation (SNP) | VAF 143/298 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1057519721, COSV67572554, COSV67587550; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ADCY8 | c.3296G>A p.G1099D | Missense Mutation (SNP) | VAF 37/248 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53912267; called by muse, mutect2, varscan2
- DBT | c.872G>A p.R291Q | Missense Mutation (SNP) | VAF 103/392 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.977); catalogued as rs775808731; called by muse, mutect2, varscan2
- DYRK1A | c.1517G>A p.G506D | Missense Mutation (SNP) | VAF 39/497 reads (8%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.581); catalogued as COSV100117401; called by muse, mutect2
- PLEKHG4B | c.996C>G p.D332E (on ENST00000283426; = p.D688E on NM_052909.5) | Missense Mutation (SNP) | VAF 63/289 reads (22%) | SIFT tolerated (0.27); PolyPhen benign (0.101); catalogued as COSV52052905; called by muse, mutect2, varscan2
- SRGAP3 | c.2824G>A p.G942S | Missense Mutation (SNP) | VAF 192/406 reads (47%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs371641995, COSV99062240; called by muse, mutect2, varscan2
- SURF6 | c.641C>T p.A214V | Missense Mutation (SNP) | VAF 101/478 reads (21%) | SIFT tolerated (0.48); PolyPhen benign (0.005); catalogued as rs782762346, COSV64395195; called by muse, mutect2, varscan2
- SYN2 | c.700G>A p.A234T | Missense Mutation (SNP) | VAF 49/245 reads (20%) | SIFT tolerated (0.1); PolyPhen benign (0.127); catalogued as rs762270296; called by muse, mutect2, varscan2
- ADCY5 | c.3011A>G p.H1004R | Missense Mutation (SNP) | VAF 173/392 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.781); called by muse, mutect2, varscan2
- GRM1 | c.3436A>G p.T1146A | Missense Mutation (SNP) | VAF 81/576 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.334); called by muse, mutect2, varscan2
- HDAC7 | c.288dup p.Q97Tfs*47 (on ENST00000427332; = p.Q136Tfs*47 on NM_015401.5 and 1 other RefSeq transcript) | Frame Shift Ins (INS) | VAF 65/331 reads (20%) | called by mutect2, pindel, varscan2
- LINGO3 | c.1607T>C p.I536T | Missense Mutation (SNP) | VAF 119/600 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.722); called by muse, mutect2, varscan2
- MYO1F | c.507C>A p.G169= | Splice Region (SNP) | VAF 22/303 reads (7%) | called by muse, mutect2
- PLCB4 | c.3071G>A p.W1024* | Nonsense Mutation (SNP) | VAF 67/227 reads (30%) | called by muse, mutect2, varscan2
- SLC22A17 | n.1663C>T | Splice Region (SNP) | VAF 35/270 reads (13%) | called by muse, mutect2, varscan2
- TMEM174 | c.593G>A p.G198D | Missense Mutation (SNP) | VAF 133/277 reads (48%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- ARL4A | c.153C>A p.T51= | Silent (SNP) | VAF 49/296 reads (17%) | called by muse, mutect2, varscan2
- CASKIN2 | c.2808T>C p.P936= | Silent (SNP) | VAF 57/844 reads (7%) | called by muse, mutect2
- MASP2 | c.1080G>A p.A360= | Silent (SNP) | VAF 66/286 reads (23%) | catalogued as rs774776055; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SLITRK2 | c.360C>T p.N120= | Silent (SNP) | VAF 103/541 reads (19%) | called by muse, mutect2, varscan2
- USH1C | c.1285-3931C>T | Intron (SNP) | VAF 51/291 reads (18%) | catalogued as rs142523327; called by muse, mutect2, varscan2
